Surgical pathology report (de-identified scan), TCGA case TCGA-DQ-7589, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University Of Michigan, specimen TCGA-DQ-7589-01A (Primary Tumor).

Reg#: [REDACTED] Name: [REDACTED] DOB: [REDACTED] Sex: [REDACTED] Age: [REDACTED] User Name: [REDACTED]

ACCN#	ACCN# Number	Order Test Code	Order Test Name	Last Updated
Collected	[REDACTED]	SPF	SP FINAL REPORT	Updated [REDACTED]
SP FINAL REPORT Source:				

HISTORY:

History of case: Right neck swelling, dysphagia and odynophagia and bilateral otalgia. Fine needle aspiration shows squamous cell carcinoma.

GROSS:

1. 'Left tongue base' Received in formalin in a small container is a 2.5 x 1.7 x 0.5 cm aggregate of pink, glistening and friable soft tissue fragments. (1 cassette, ns)
2. "Left A-E fold" Received in formalin in a small container is a 2.6 x 1.6 x 0.4 cm aggregate of pink-red, friable soft tissue fragments. (1 cassette, ns)

MICROSCOPIC DIAGNOSIS:

1. Left tongue base, biopsy: Invasive basaloid squamous cell carcinoma.
2. Left aryepiglottic fold, biopsy: Invasive basaloid squamous cell carcinoma.

I [REDACTED] the signing staff pathologist, have personally examined and interpreted the slides from this case.

(electronic signature)

Close

Source: NCI Genomic Data Commons file eb91e635-99cf-4f4c-be58-031e64f23c4c (TCGA-DQ-7589.812223E2-3415-4A18-A6DC-44666E1402A5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).